Somatic mutation profile of tumor specimen 0DFA9C from CCDI case PBBRJL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 0.2 years (74 days).
Specimen 0DFA9C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae994773-75d2-4697-b4e2-f2323b6a96d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFA8Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aaed9d7c-1a63-4385-9b96-ae3237c751fa

The open-access MAF lists 5 somatic variants for this specimen: 1 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, 5'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGD4 | c.484G>C p.G162R | Missense Mutation (SNP) | VAF 192/394 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as rs774679169; ClinVar: uncertain significance; called by muse, varscan2
- CWF19L1 | c.505-74A>G | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 8/64 reads (13%) | called by muse, varscan2
- MORC2 | c.69-92C>G | Intron (SNP) | VAF 6/46 reads (13%) | called by muse, varscan2
- SKIDA1 | c.-61T>C | 5'UTR (SNP) | VAF 12/118 reads (10%) | catalogued as rs1015442172; called by muse, varscan2
